CGCI case HTMCP-02-03-01004 — HIV+ Tumor Molecular Characterization Project - Lung Cancer (CGCI-HTMCP-LC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/61d19d17-c18d-488f-8aa2-7140168af673

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 59 years.

Diagnoses (2)
1. Adenocarcinoma with mixed subtypes (the primary disease): ICD-O-3 morphology code: 8255/3; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 59.9 years (21,863 days); Year of diagnosis: 2009; Method of diagnosis: Excisional Biopsy; AJCC staging edition: 6th; AJCC clinical T: T1; AJCC clinical N: N0; AJCC clinical M: MX; AJCC clinical stage: Stage IA; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IA; Prior malignancy: yes; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,599 days (4.4 years).
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 3.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Neoplasm, NOS: Tissue or organ of origin: Colon, NOS; Classification of tumor: Prior primary.

Follow-up (3 entries)
- Days to follow up: 0 days; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,599 days (4.4 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 7.

Other clinical attributes
- Day 0: AIDS risk factors: Cytomegalovirus.
- Day 0: Cdc hiv risk factors: Heterosexual Contact.
- Day 0: Weight: 55 kg; Height: 177 cm; BMI: 17.6; CD4 count: 30; Haart treatment indicator: No; HIV viral load: 97207.
- Day 7: Risk factors: HIV/AIDS.
- Day 7: Comorbidities: HIV/AIDS.

Exposures
- Tobacco smoking status: Current Smoker; Pack years smoked: 50.

Biospecimens (2 samples)
- Sample HTMCP-02-03-01004-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-02-03-01004-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Adenocarcinoma, mixed; Tumor status: Tumor free; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: Yes; Tobacco smoking history indicator: 2; New tumor event diagnosis indicator: No.
- Anatomic neoplasm subdivision list: Anatomic organ subdivision: Upper lobe.
- History of disease: HIV status: Positive; Days to HIV diagnosis: 7; Haart therapy at diagnosis: No; Haart therapy prior to diagnosis: No; Prior aids conditions: CMV other than liver, spleen or nodes, onset at age >1month.
- Primary pathology: Lymph nodes examined: Yes; Days from index date to tumor sample procurement: 30.
